CCDI case PBCFME — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/f7b89fa0-fc75-4cb1-ba6a-f8b36aab5072

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 8240/3; Tissue or organ of origin: Middle lobe, lung; Age at diagnosis: 17.8 years (6,508 days).

Biospecimens (3 samples)
- Sample 0DQRZY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQS07: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQS0P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
